Somatic mutation profile of tumor specimen BA2787D (aliquot aq-BA2787D) from BEATAML1.0 case 2447, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.4 years (21,314 days).
Specimen BA2787D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a113d5c-9b4c-4c91-a1e6-d53b11c95cfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2920D (Solid Tissue Normal), aliquot aq-BA2920D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f579acc-8d19-4b60-bb38-06e986f43495

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHIP | c.2201G>T p.S734I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV51504606, COSV99244085; called by muse, mutect2
- SPOCK3 | c.1063A>G p.S355G | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1448070251; called by muse, mutect2
- ADGRG3 | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- ARMCX5-GPRASP2 | c.287C>A p.S96Y | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- ITPR3 | c.827C>A p.A276D | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MVP | c.1802C>A p.T601N | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.165); called by muse, mutect2
- PTPRU | c.975C>A p.R325= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
